Surgical pathology report (de-identified scan), TCGA case TCGA-27-1836, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-1836-01A (Primary Tumor).

Ref. Number

Gender

Birth date

Tumor site

Right parietal

Histological diagnosis

Glioblastoma multiforme

Source: NCI Genomic Data Commons file a7b8b23d-ecb7-4c0b-b4bc-07129d6243b3 (TCGA-27-1836.FE622CD0-E679-4A07-9329-BB2A8F9D2C0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).